Somatic mutation profile of tumor specimen TCGA-05-5420-01A (aliquot TCGA-05-5420-01A-01D-1625-08) from TCGA case TCGA-05-5420, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.0 years (24,472 days).
Specimen TCGA-05-5420-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fe6f1f9-2825-47e1-84cd-6e45a6b34d9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-5420-11A (Solid Tissue Normal), aliquot TCGA-05-5420-11A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84bd7d30-18aa-4178-99ff-717360005681

The open-access MAF lists 90 somatic variants for this specimen: 62 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 24, Nonsense Mutation 6, RNA 2, Frame Shift Del 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as rs972341316, CM144583, COSV60802547; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55943015; called by muse, mutect2
- ADAMTS12 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV61283315; called by muse, mutect2, varscan2
- ARHGAP26 | c.450T>G p.N150K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV50844176; called by muse, mutect2, varscan2
- AUP1 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs746538427, COSV51216772; called by muse, mutect2, varscan2
- BMS1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs771571475, COSV65735802; called by muse, mutect2, varscan2
- C3AR1 | c.1177T>C p.Y393H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749061121, COSV99368466; called by muse, mutect2, varscan2
- CCNE1 | c.647T>A p.V216E | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52906111; called by muse, mutect2
- CD93 | c.1486C>A p.R496S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55669466, COSV99079361; called by muse, mutect2, varscan2
- CFAP47 | c.4876C>A p.Q1626K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV57973352; called by muse, mutect2, varscan2
- CHD3 | c.4385A>G p.H1462R | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57881367; called by muse, mutect2, varscan2
- COBLL1 | c.1282G>T p.G428* (on ENST00000392717; = p.G390* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV99527839; called by muse, mutect2
- CTSV | c.521del p.G174Afs*32 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | catalogued as COSV52345880; called by mutect2, pindel, varscan2
- DENND2B | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs200023000, COSV58206269, COSV58208448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMC1 | c.2935A>T p.T979S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as COSV64346825; called by muse, mutect2, varscan2
- FANCI | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 21/187 reads (11%) | catalogued as COSV100167909; called by muse, mutect2, varscan2
- GDA | c.655T>A p.S219T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV52998664; called by muse, mutect2, varscan2
- GPR158 | c.2367G>C p.R789S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV66285100; called by muse, mutect2, varscan2
- GRIA2 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV52409693; called by muse, mutect2, varscan2
- HAVCR2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57152484; called by muse, mutect2, varscan2
- KCNH7 | c.1843G>T p.V615F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV59816988; called by muse, mutect2, varscan2
- KRT31 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99289471, COSV99289714; called by muse, mutect2, varscan2
- LRRC4B | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65350437; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1139A>G p.D380G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV51728376; called by muse, mutect2, varscan2
- MSRB2 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV64738176; called by muse, mutect2, varscan2
- NR6A1 | c.536C>G p.S179C (on ENST00000487099 / NM_033334.4; = p.S175C on NM_001489.5) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs776287206, COSV60639124; called by muse, mutect2, varscan2
- OR1S2 | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV56921122; called by muse, varscan2
- OR2T11 | c.246G>C p.M82I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV58185567, COSV58187562; called by muse, mutect2, varscan2
- OR4A16 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs371963500; called by muse, mutect2, varscan2
- OR52N1 | c.725C>A p.T242N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57693407; called by muse, mutect2, varscan2
- OR52R1 | c.756G>T p.L252F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61889632; called by muse, mutect2, varscan2
- PAPPA2 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100866479, COSV62788373; called by muse, mutect2
- PCDHGA3 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54051025; called by muse, mutect2, varscan2
- PRSS22 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99361831; called by muse, mutect2, varscan2
- RIPK3 | c.398A>T p.D133V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV53477932; called by muse, mutect2
- RNF144B | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52573455, COSV52573691; called by muse, mutect2
- SEC24D | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54885758; called by muse, mutect2
- SHOX | c.203T>A p.V68E | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100479321, COSV61862602; called by muse, mutect2
- SIGLEC14 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV55784739; called by muse, mutect2, varscan2
- SLC25A10 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs368648459; called by muse, mutect2, varscan2
- SLF2 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as COSV53280940; called by muse, mutect2, varscan2
- SPG11 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99968518; called by muse, mutect2
- STK31 | c.1162A>T p.K388* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as COSV63460078; called by muse, mutect2
- STRIP2 | c.2369T>C p.V790A | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV50810242; called by muse, mutect2, varscan2
- TAS2R1 | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.111); catalogued as COSV66778737, COSV66778995; called by muse, mutect2
- TMC1 | c.1853G>T p.C618F | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1300900067, COSV52786983; called by muse, mutect2
- TMEM132B | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV100169554; called by muse, mutect2
- TMEM19 | c.501C>A p.Y167* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV56999984; called by muse, mutect2, varscan2
- TMPRSS15 | c.2607T>A p.N869K | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV53051015; called by muse, mutect2
- TRIM50 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.873); catalogued as COSV60796408; called by muse, mutect2
- TTK | c.1927A>C p.I643L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100036098, COSV57887389; called by muse, mutect2, varscan2
- TTYH1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV100001991; called by muse, mutect2, varscan2
- UBC | c.527A>C p.E176A | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); catalogued as COSV60061949; called by muse, mutect2
- USP28 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50155482, COSV50200584; called by muse, mutect2
- WDR38 | c.703T>A p.W235R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62161507, COSV62161562; called by muse, mutect2, varscan2
- ZNF10 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50215972; called by muse, mutect2, varscan2
- ZNF155 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV99525625; called by muse, mutect2, varscan2
- ZNF486 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs1210141178, COSV58718740; called by muse, mutect2, varscan2
- ZNF536 | c.2259C>G p.C753W | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62823904, COSV62836273; called by muse, mutect2
- CYP4F12 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); called by muse, mutect2
- FCGBP | c.8167T>A p.W2723R | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAL3ST3 | c.325del p.R109Afs*131 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- BRCA1 | c.2004C>T p.L668= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs1057520832, COSV58801856; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDCP1 | c.1548C>A p.T516= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV56108625; called by muse, mutect2
- COL4A1 | c.3834T>C p.G1278= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV65432982; called by muse, mutect2, varscan2
- CPAMD8 | c.2667G>A p.S889= (on ENST00000651564; = p.S842= on NM_015692.5) | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as rs372485212; called by muse, mutect2
- DNAJC4 | c.120G>A p.G40= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99655804; called by mutect2, varscan2
- F8 | c.6225C>T p.S2075= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs782559263, COSV64279614; called by muse, mutect2
- FANCI | c.801G>C p.V267= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as COSV100167907; called by muse, mutect2, varscan2
- KDELR2 | c.384C>T p.S128= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs766520018, COSV51726760; called by muse, mutect2, varscan2
- LRRTM3 | c.469C>A p.R157= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as rs1397779714, COSV63665579; called by muse, mutect2, varscan2
- MON2 | c.2544A>T p.T848= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV54816693; called by muse, mutect2, varscan2
- NR1H4 | c.687T>C p.H229= (on ENST00000551379 / NM_001206993.2; = p.H215= on NM_005123.4) | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV51857825; called by muse, mutect2, varscan2
- OR1N1 | c.264C>T p.H88= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV59197082; called by muse, mutect2, varscan2
- ORC1 | c.141C>T p.I47= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV57123521; called by muse, mutect2, varscan2
- PKHD1L1 | c.4599G>T p.V1533= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV101006041; called by muse, mutect2, varscan2
- PNRC2 | c.102C>T p.S34= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- ROR2 | c.1608C>T p.V536= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs747797208, COSV65224283; called by muse, mutect2, varscan2
- S1PR2 | c.825C>T p.A275= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs201255057, COSV100495312; called by mutect2, varscan2
- SLC39A6 | c.1797G>T p.V599= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV52371813; called by muse, mutect2
- SPG11 | c.219G>T p.R73= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99968523; called by muse, mutect2
- TAS2R60 | c.556C>A p.R186= | Silent (SNP) | VAF 25/180 reads (14%) | catalogued as COSV60332390; called by muse, mutect2, varscan2
- TMEM234 | c.252G>T p.V84= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV59085903; called by muse, mutect2
- TRIM10 | c.6C>A p.A2= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV64990645; called by muse, mutect2
- VENTX | c.465G>A p.L155= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV58085548; called by muse, mutect2, varscan2
- ZNF155 | c.75G>A p.L25= | Silent (SNP) | VAF 56/255 reads (22%) | catalogued as rs1487897441, COSV99525621; called by muse, mutect2, varscan2
- AC103796.1 | n.148-24894C>A | Intron (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100151149; called by muse, mutect2, varscan2
- FAM183BP | n.1021G>A | RNA (SNP) | VAF 8/75 reads (11%) | catalogued as rs1345186615; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142670792 C>T | 3'Flank (SNP) | VAF 4/13 reads (31%) | catalogued as rs1563209179; called by muse, mutect2
- SPATA8 | n.754G>T | RNA (SNP) | VAF 14/99 reads (14%) | catalogued as COSV60705773; called by muse, mutect2, varscan2
